CCDI case PBBPJV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/dad0b4d3-4007-496e-b6a3-dc7f949534af

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Eyelid; Age at diagnosis: 6.1 years (2,241 days).

Biospecimens (3 samples)
- Sample 0DEHMY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DEHNW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DEHPK: Tissue type: Tumor; Specimen type: Solid Tissue.
